Somatic mutation profile of tumor specimen MMRF_2217_1_BM_CD138pos (aliquot MMRF_2217_1_BM_CD138pos_T1_KHS5U_L08838) from MMRF case MMRF_2217, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,220 days).
Specimen MMRF_2217_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeb9aeab-6863-44fc-b398-286325dc45ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2217_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2217_2_PB_Whole_C1_KHS5U_L08770; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c05b1e71-6e7d-4c69-9953-57e48ce7a01b

The open-access MAF lists 108 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 31, Silent 9, Intron 9, 5'UTR 5, Frame Shift Del 3, 3'Flank 3, RNA 3, Nonsense Mutation 3, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRNL1 | c.3130A>G p.M1044V | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs1554936031; called by muse, mutect2, varscan2
- DAPK1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs759393262; called by muse, mutect2, varscan2
- FREM1 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100772211; called by muse, mutect2, varscan2
- GALNT18 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1236782243; called by muse, mutect2, varscan2
- H2BC9 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs780484864; called by muse, mutect2, varscan2
- HSF1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68822113, COSV68822188; called by muse, mutect2, varscan2
- IGLV3-1 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 117/184 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as rs534241034; called by muse, mutect2, varscan2
- MAGED1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV58516107, COSV58516397; called by muse, mutect2, varscan2
- MEGF9 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 40/275 reads (15%) | catalogued as COSV64237246; called by muse, mutect2, varscan2
- MYO6 | c.3544C>T p.R1182C (on ENST00000369981; = p.R1172C on NM_004999.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752568854; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, varscan2
- OR3A2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as rs375263331; called by muse, mutect2, varscan2
- PAPPA | c.4558G>A p.V1520M | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs770571982, COSV60278761; called by muse, mutect2, varscan2
- SORL1 | c.3827C>T p.T1276M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs773791624, CM164117, COSV52757709; called by muse, mutect2, varscan2
- TECTA | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs765578527, COSV104382540; called by muse, mutect2, varscan2
- TEKT3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1241081916, COSV58628129; called by muse, mutect2, varscan2
- ZIC4 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67171067; called by muse, mutect2, varscan2
- ZNF57 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032218324; called by muse, mutect2
- ADRA2C | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP2B1 | c.2453G>A p.C818Y | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- AQR | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BMP6 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAD | c.5835C>A p.H1945Q | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARF | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCSER1 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CHD4 | c.660del p.S221Vfs*14 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- EBF1 | c.43A>C p.M15L | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA4 | c.762T>A p.N254K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- FRMD4B | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- FUT7 | c.279_290del p.F93_E97delinsL | In Frame Del (DEL) | VAF 9/41 reads (22%) | called by pindel, varscan2
- IQCJ-SCHIP1 | c.727G>T p.V243L (on ENST00000485419 / NM_001197113.1; = p.V167L on NM_014575.3) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF7 | c.1838A>G p.N613S | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTDH | c.284_293del p.V95Gfs*9 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- MYH1 | c.5124G>T p.Q1708H | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OGA | c.2467A>T p.S823C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PPIH | c.66+3G>A | Splice Region (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- PTPRJ | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 98/182 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RRNAD1 | c.344A>C p.N115T | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SEC24D | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEZ6L2 | c.470T>A p.I157N (on ENST00000308713 / NM_001114099.3; = p.I87N on NM_012410.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC14A2 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2
- SLC4A7 | c.3026G>C p.R1009P | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB1 | c.5114A>G p.D1705G | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- TENT5C | c.358del p.L120Cfs*5 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- TENT5C | c.1019_1020dup p.L341Cfs*57 | Frame Shift Ins (INS) | VAF 18/198 reads (9%) | called by mutect2, pindel
- TRIM71 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); called by muse, mutect2
- ZBTB38 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ACSL6 | c.1671G>A p.K557= (on ENST00000379240; = p.K582= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as rs748644268; called by muse, mutect2, varscan2
- IARS2 | c.2238C>T p.S746= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as rs1441129862; called by muse, mutect2, varscan2
- IGHD2-15 | c.21G>A p.*7= | Silent (SNP) | VAF 38/39 reads (97%) | catalogued as rs548172531; called by mutect2, varscan2
- KLHDC4 | c.1008C>T p.D336= | Silent (SNP) | VAF 52/217 reads (24%) | catalogued as rs146256092; called by muse, mutect2, varscan2
- KLHL1 | c.90C>T p.G30= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as rs764920556, COSV64780027; called by muse, mutect2, varscan2
- LGSN | c.399T>C p.N133= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs1299186005; called by muse, mutect2, varscan2
- NFX1 | c.1041A>G p.L347= | Silent (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- PHLPP1 | c.5061G>A p.Q1687= | Silent (SNP) | VAF 76/135 reads (56%) | called by muse, mutect2, varscan2
- SAMD7 | c.381C>T p.L127= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as rs758964286, COSV59420942; called by muse, mutect2, varscan2
- AASDHPPT | c.*1568A>C | 3'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- ABCA5 | c.*25T>A | 3'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- AC083849.1 | n.480C>A | RNA (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- ACOT13 | c.-20A>G | 5'UTR (SNP) | VAF 71/157 reads (45%) | catalogued as COSV100015879; called by muse, mutect2, varscan2
- AKT2 | c.*1329G>C | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- ALX4 | c.*733C>A | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- AZGP1 | c.*161G>C | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- CBX5 | c.*2079G>A | 3'UTR (SNP) | VAF 58/104 reads (56%) | catalogued as rs1244907827; called by muse, mutect2, varscan2
- CDO1 | c.*212T>C | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CXCL9 | c.*1006C>T | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- DEPDC1B | c.49-1780T>G | Intron (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- DNAH10 | c.12441+25G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs755101065; called by mutect2, varscan2
- EIF4G2 | c.*746A>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ERVH48-1 | c.-13C>T | 5'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs1568865988; called by muse, mutect2, varscan2
- ETV1 | chr7:13893509 T>G | 3'Flank (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- FAM210B | c.*2205_*2213del | 3'UTR (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- FLG | c.*17G>T | 3'UTR (SNP) | VAF 99/188 reads (53%) | called by muse, mutect2, varscan2
- HIVEP2 | c.*586A>G | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- HSPA9 | c.1728+21G>A | Intron (SNP) | VAF 22/74 reads (30%) | catalogued as rs368579099, COSV51864958; called by muse, mutect2, varscan2
- ID4 | c.-312G>A | 5'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- IKZF2 | c.*817G>A | 3'UTR (SNP) | VAF 30/138 reads (22%) | called by muse, mutect2, varscan2
- KCNJ16 | c.*61G>A | 3'UTR (SNP) | VAF 27/49 reads (55%) | catalogued as rs551085693, COSV99388656; called by muse, mutect2, varscan2
- KDSR | c.*153G>T | 3'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- KIRREL3 | c.*1195A>G | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- KLHL5 | c.2211+864A>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- KRT38 | c.*109C>G | 3'UTR (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- L3MBTL1 | c.361-28G>A | Intron (SNP) | VAF 30/114 reads (26%) | catalogued as rs1380181085; called by muse, mutect2, varscan2
- LACTB2 | c.*428A>C | 3'UTR (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- LRRC27 | chr10:132378491 G>A | 3'Flank (SNP) | VAF 12/76 reads (16%) | catalogued as rs943420573; called by muse, mutect2, varscan2
- MIR99AHG | n.574G>A | RNA (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2
- MXRA5Y | n.71C>T | RNA (SNP) | VAF 47/48 reads (98%) | called by muse, mutect2, varscan2
- MYO1E | c.-6G>A | 5'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- NDC1 | c.*33T>G | 3'UTR (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- NECTIN3 | c.*479T>A | 3'UTR (SNP) | VAF 21/78 reads (27%) | catalogued as COSV60550235; called by muse, mutect2, varscan2
- NRG3 | c.823+1866A>G | Intron (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- OR4D10 | c.*9del | 3'UTR (DEL) | VAF 124/247 reads (50%) | catalogued as rs200783661; called by mutect2, varscan2
- PCDH15 | c.*1705T>A | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PNMA2 | c.*2097G>A | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2
- POLQ | c.*633A>G | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.150+913A>G | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- RNF14 | c.*1994A>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- RPN2 | c.*125T>A | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- RPRD1B | c.*2320A>G | 3'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs764392456, COSV65033133; called by muse, mutect2, varscan2
- RTTN | c.6525+119T>G | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- SELENOI | c.*4944T>G | 3'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- SLFN13 | c.*472G>T | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- SNPH | c.*3017A>C | 3'UTR (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- SYNPO | chr5:150656834 del TCGCGCCCA | 3'Flank (DEL) | VAF 22/39 reads (56%) | called by mutect2, pindel, varscan2
- TMSB4X | chrX:12975598 T>A | 5'Flank (SNP) | VAF 82/83 reads (99%) | called by muse, varscan2
- TNXB | c.2358+1698C>T | Intron (SNP) | VAF 26/42 reads (62%) | called by muse, mutect2, varscan2
- ZBTB43 | c.-880T>G | 5'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- ZNF827 | c.*234C>T | 3'UTR (SNP) | VAF 27/101 reads (27%) | catalogued as rs1049304017, COSV65226923; called by muse, mutect2, varscan2
